Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040036-03A.4 (aliquot TARGET-15-SJMPAL040036-03A.4-01D) from TARGET case TARGET-15-SJMPAL040036, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,983 days).
Specimen TARGET-15-SJMPAL040036-03A.4: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c6707f0-597f-4e39-83da-ab7bc8790ef0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040036-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040036-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bf75d92-6c79-4cac-b63b-53b16188477d

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 2, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15061C>T p.R5021* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as rs587783695, CM122109, COSV56415919; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID5B | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54425390; called by muse, mutect2
- FCN2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs767686429; called by muse, mutect2, varscan2
- GOLGA8S | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571480938; called by mutect2, varscan2
- OPLAH | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs781820857, COSV101470796; called by muse, mutect2, varscan2
- PLAAT1 | c.389G>A p.R130H (on ENST00000650797; = p.R25H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs150318874; called by muse, mutect2, varscan2
- TNIP3 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs778852023, COSV50249949; called by muse, mutect2, varscan2
- WT1 | c.1072delinsGG p.R358Gfs*15 | Frame Shift Ins (INS) | VAF 46/153 reads (30%) | catalogued as COSV60069873, COSV60081928; called by pindel, varscan2*
- CEP350 | c.5740C>A p.L1914M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); called by muse, mutect2
- CHD5 | c.5140G>T p.E1714* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- FKBP15 | c.2337G>T p.L779F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GJC2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- LONRF3 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTN1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCLO | c.3841G>T p.A1281S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- RUNX1 | c.540_541insAGGG p.Q181Rfs*6 (on ENST00000344691 / NM_001001890.3; = p.Q208Rfs*6 on NM_001754.5) | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- TRAF3IP3 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- VSTM2A | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF415 | c.339C>T p.A113= | Silent (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505225 C>A | 5'Flank (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- CA9 | chr9:35669648 C>A | 5'Flank (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- SLAMF8 | chr1:159841221 C>A | 3'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
